Surgical pathology report (de-identified scan), TCGA case TCGA-MQ-A6BS, project TCGA-MESO (Mesothelioma), tissue source site Washington University - NYU, specimen TCGA-MQ-A6BS-01A (Primary Tumor).

[page 1 of 4]
THIS IS A CONFIDENTIAL AND PRIVILEGED COMMUNICATION
PLEASE DISPOSE OF PAPER COPIES APPROPRIATELY

Printed by:

Name: [REDACTED]

Age:

Test Name: RIGHT RIB 8{PLEURA, RIGHT {DIAPHRAGMATIC PLEURA,
RIGHT{RIGHT LOWER LOBE NODULE 1{RT. MIDDLE LOBE NODULE
{LEVEL 4 LYMPH NODE, RIGHT{LEVEL 9 LYMPH NODE, RIGHT{LEVEL 7
LYMPH NODE, RIGHT{THORACOSCOPY, PORT SITE 1, RIGHT
{THORACOSCOPY, PORT SITE 2, RIGHT

Test Date:

Ordered By:

Mesothelioma, epithelioid
9052/3
Site: Pleura NOS
038.4
JW 5/16/13

SURGICAL PATHOLOGY REPORT

SPECIMEN NUMBER: [REDACTED]
COLLECTION DATE:

SPECIMENS:

1. RIGHT RIB 8
2. PLEURA, RIGHT
3. DIAPHRAGMATIC PLEURA, RIGHT
4. RIGHT LOWER LOBE NODULE 1
5. RT. MIDDLE LOBE NODULE
6. LEVEL 4 LYMPH NODE, RIGHT
7. LEVEL 9 LYMPH NODE, RIGHT
8. LEVEL 7 LYMPH NODE, RIGHT
9. THORACOSCOPY, PORT SITE 1, RIGHT
10. THORACOSCOPY, PORT SITE 2, RIGHT
11. AZYGIOUS VEIN, RIGHT

DIAGNOSIS:

1. RIB #8, RIGHT: EXCISION
- BONE AND BONE MARROW WITH TRILINEAGE MATURATION.
2. PLEURA, RIGHT: EXCISION
- MALIGNANT MESOTHELIOMA, EPITHELIOD TYPE, INFILTRATING ADIPOSE TISSUE.
- FOCAL FOREIGN BODY GIANT CELL REACTION AND BIREFRINGENT MATERIAL SUGGESTIVE OF TALC PLEURODESIS.
3. DIAPHRAGMATIC PLEURA, RIGHT: EXCISION
- MALIGNANT MESOTHELIOMA, EPITHELIOD TYPE, INFILTRATING ADIPOSE TISSUE AND SKELETAL MUSCLE.
4. LUNG, RIGHT LOWER LOBE, NODULE #1: WEDGE RESECTION

[page 2 of 4]
-
- **MALIGNANT MESOTHELIOMA, EPITHELIOD TYPE, INVOLVING LUNG PARENCHYMA.**
- **PARENCHYMAL MARGIN NEGATIVE FOR TUMOR. SEE NOTE.**

NOTE:

Immunostains on part 4 (right lower lobe nodule) demonstrate that the tumor cells are positive for CK5/6, D2-40, WT-1 (weak, focal) and negative for TTF-1. The stain for Calretinin is non-contributory. This immunoprofile supports the diagnosis of malignant mesothelioma.

5. LUNG, RIGHT MIDDLE LOBE, NODULE: WEDGE RESECTION

- **MALIGNANT MESOTHELIOMA, EPITHELIOD TYPE, INVOLVING LUNG PARENCHYMA.**
- **PARENCHYMAL MARGIN NEGATIVE FOR TUMOR.**

6. LYMPH NODE, LEVEL 4, RIGHT: EXCISION

- **FIVE LYMPH NODES, NEGATIVE FOR MESOTHELIOMA (0/5).**

7. LYMPH NODE, LEVEL 9, RIGHT: EXCISION

- **ONE LYMPH NODE, NEGATIVE FOR MESOTHELIOMA (0/1).**

8. LYMPH NODE, LEVEL 7, RIGHT: EXCISION

- **THREE LYMPH NODES, NEGATIVE FOR MESOTHELIOMA (0/3).**

9. THORACOSCOPY PORT SITE #1, RIGHT: EXCISION

- **SKIN WITH MILD DERMAL FIBROSIS.**

10. THORACOSCOPY PORT SITE #2, RIGHT: EXCISION

- **SKIN WITH MILD DERMAL FIBROSIS AND LYMPHOHISTIOCYTIC INFILTRATE.**

11. AZYGOUS VEIN, RIGHT: EXCISION

- **VEIN WITH NO SIGNIFICANT ALTERATIONS.**

Pathologist

CLINICAL HISTORY AND PRE - OPERATIVE DIAGNOSIS:
Mesothelioma.

MACROSCOPIC DESCRIPTION:

The specimen is received in eleven parts, each labeled with the patient's name.

1. Part one is received in formalin, labeled 'right rib #8'. It consists of three fragments of bone ranging from 4 to 8.2 cm in length. The outer surface is smooth and shows scant attached fibromuscular tissue. Sectioning reveals an unremarkable marrow. Representative section is submitted in one cassette following decalcification.
2. Part two is labeled 'pleura, right'. It consists of three irregular fragments of pleural tissue measuring 31 x 19 x 1 cm. The parietal pleural surface shows focal adipose tissue. The wall thickness ranges from 0.1 to 0.6 cm. Multiple small firm nodules are noted studded on the pleural surface. These nodules range from 0.2 to 1.5 cm in greatest dimension. Representative sections are submitted in five cassettes.

[page 3 of 4]
3. Part three is received in saline, labeled 'diaphragmatic pleura, right'. It consists of pleural tissue fragments ranging 14 x 10 x 1.5 cm. Focally yellow lobulated adipose tissue is attached. The remainder of the pleura is gray-purple and shows multiple thickened nodular areas ranging from 0.5 to 2.0 cm in greatest dimension. Cut surface of these nodules is white, firm. Representative sections of these nodules are submitted in four cassettes.

4. Part four is received in saline, labeled 'right lower lobe nodule #1'. It consists of a wedge of lung measuring 6 x 2.5 x 0.8 cm. The staple line is inked. The pleural surface is gray-purple and shows a well-defined firm tan lesion measuring 1.5 x 1 x 0.4 cm. Representative sections are submitted.

5. Part five is received in saline, labeled 'right middle lobe nodule'. It consists of a wedge of lung measuring 4.2 x 1.8 x 0.5 cm. The staple line is inked black. The pleural surface is gray-purple and shows a well-circumscribed pleural based lesion measuring 1.2 x 0.7 cm. Cut surface of the lesion is tan and extends into the lung parenchyma. The lesion is 0.7 cm from the staple margin. Representative sections are submitted.

6. Part six is received in saline, labeled 'level 4 lymph node, right'. It consists of a portion of fibrofatty tissue measuring 3.5 x 2 x 1.5 cm. Four possible gray-black lymph nodes ranging from 0.8 to 1.2 cm are noted. Entirely submitted in two cassettes.

7. Part seven is received in saline, labeled 'level 9 lymph node, right'. It consists of a single fragment of tan-brown firm tissue measuring 0.6 x 0.4 x 0.2 cm. Totally submitted in one cassette.

8. Part eight is received in saline, labeled 'level 7 lymph node, right'. It consists of two fragments of tissue composed of group of gray-black lymph nodes measuring 2.5 x 1.5 x 0.5 cm and 3 x 1 x 0.4 cm. The entire specimen is submitted in two cassettes.

9. Part nine is received in saline, labeled 'thoracoscopy port site #1, right'. It consists of an ellipse of skin measuring 2.2 x 0.5 cm, excised to a depth of 0.5 cm. The skin's surface is tan-white and shows a linear scar measuring 1.3 cm in length. Representative sections are submitted in one cassette.

10. Part ten is received in saline, labeled 'thoracoscopy port site #2, right'. It consists of an ellipse of skin measuring 2.5 x 0.5 cm, excised to a depth of 1.5 cm. The skin's surface is tan-pink and shows a linear scar measuring 1.5 cm in length. The underlying soft tissue appears unremarkable. Representative section is submitted in one cassette.

11. Part eleven is received in saline, labeled 'right azygous vein'. It consists of a segment of vein measuring 1.7 cm in length and 0.6 cm in diameter. The outer surface is tan-pink and unremarkable. Representative section is submitted in one cassette.

SUMMARY OF SECTIONS:

1A representative

2A-2E representative

3A-3D representative

[page 4 of 4]
4A-4B entire firm lesion
4C unremarkable lung
4D stapled margin
5A-5B entire lesion
5C uninvolved lung
5D stapled margin
6A two lymph nodes
6B two lymph nodes
7A in toto
8A-8B in toto
9A representative
10A representative
11A representative

SPECIAL PROCEDURES:
Decalcification.

Final Diagnosis performed by

Electronically signed

The electronic signature attests that the named Attending Pathologist has evaluated the specimen referred to in the signed section of the report and formulated the diagnosis therein.

This report may include one or more immunohistochemical stain results that use analyte specific reagents.

The tests were developed and their performance characteristics determined by

They have not been cleared or approved by the US Food and Drug Administration.

The FDA has determined that such clearance or approval is not necessary.

Source: NCI Genomic Data Commons file 2b8da59e-4f5c-46a0-af7d-7ffb438a6fda (TCGA-MQ-A6BS.83140BDC-6F68-411D-A30D-A99FD2112609.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).